Somatic mutation profile of tumor specimen C3N-04278-01 (aliquot CPT0245450006) from CPTAC case C3N-04278, project CPTAC-3 (Larynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 71.9 years (26,252 days).
Specimen C3N-04278-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0e2d0eae-bed9-4282-bfea-efe4e33d632c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-04278-31 (Blood Derived Normal), aliquot CPT0245490002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cec343a2-6b8b-41a1-b894-bfc8ff89be5a

The open-access MAF lists 348 somatic variants for this specimen: 253 protein-altering or splice-affecting, 59 silent, 36 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 208, Silent 59, Nonsense Mutation 28, Intron 15, Frame Shift Del 7, RNA 6, Splice Site 6, 5'UTR 6, 3'UTR 4, 5'Flank 3, Frame Shift Ins 2, 3'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD11 | c.893-1G>C p.X298_splice | Splice Site (SNP) | VAF 43/246 reads (17%) | catalogued as rs1567583835; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRCA1 | c.1082C>G p.S361* | Nonsense Mutation (SNP) | VAF 51/193 reads (26%) | catalogued as rs397508833, CM096580; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DYSF | c.5078G>A p.R1693Q | Missense Mutation (SNP) | VAF 57/365 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as rs779987458, CM053206, COSV50280819; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- RPGRIP1L | c.3446T>A p.I1149N | Missense Mutation (SNP) | VAF 33/245 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs766943204, COSV50907339; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 299/585 reads (51%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AC006059.2 | c.2206G>A p.G736S | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs754010521, COSV99067130; called by muse, mutect2, varscan2
- ACSM5 | c.240G>T p.W80C | Missense Mutation (SNP) | VAF 76/337 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59371755; called by muse, mutect2, varscan2
- ADAM32 | c.611C>T p.S204F | Missense Mutation (SNP) | VAF 31/146 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65953616; called by muse, mutect2, varscan2
- ADCY2 | c.2857G>A p.A953T | Missense Mutation (SNP) | VAF 33/296 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as rs145761834; called by muse, mutect2, varscan2
- ALKBH6 | c.42C>G p.F14L (on ENST00000252984 / NM_001297701.2; = p.F42L on NM_032878.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/329 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as rs767549818; called by muse, mutect2, varscan2
- AMZ1 | c.110C>A p.S37Y | Missense Mutation (SNP) | VAF 184/784 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs534897386, COSV56688533; called by muse, mutect2, varscan2
- ANKRD30A | c.739A>C p.T247P (on ENST00000611781; = p.T191P on NM_052997.2) | Missense Mutation (SNP) | VAF 24/155 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.078); catalogued as COSV100652618; called by muse, mutect2, varscan2
- APLNR | c.349G>A p.V117I | Missense Mutation (SNP) | VAF 53/455 reads (12%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.98); catalogued as rs750760773, COSV57242589; called by muse, mutect2, varscan2
- ASIC4 | c.360C>G p.I120M | Missense Mutation (SNP) | VAF 88/531 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.881); catalogued as COSV61731209, COSV61732009; called by muse, mutect2, varscan2
- B3GAT2 | c.595C>T p.R199* | Nonsense Mutation (SNP) | VAF 12/81 reads (15%) | catalogued as rs750513549, COSV100017508, COSV57769997, COSV57775208; called by muse, mutect2
- BRCA1 | c.2591C>T p.S864L | Missense Mutation (SNP) | VAF 31/141 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs80357003, CM042674, COSV100525515; ClinVar: uncertain significance; called by muse, mutect2
- BRCA1 | c.1274C>T p.S425F | Missense Mutation (SNP) | VAF 47/210 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.893); catalogued as rs1260879887; called by muse, mutect2, varscan2
- CABIN1 | c.381G>T p.W127C | Missense Mutation (SNP) | VAF 133/341 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs769009731; called by muse, mutect2, varscan2
- CCDC57 | c.539C>T p.S180L | Missense Mutation (SNP) | VAF 92/386 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as rs556146604; called by muse, mutect2, varscan2
- CDKN2A | c.242C>A p.P81H | Missense Mutation (SNP) | VAF 422/803 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM080133, COSV58683884, COSV58697231, COSV58717232; called by muse, mutect2, varscan2
- CHP2 | c.148G>C p.D50H | Missense Mutation (SNP) | VAF 67/568 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1339686013; called by muse, mutect2, varscan2
- CNGA1 | c.1693G>A p.G565S | Missense Mutation (SNP) | VAF 107/279 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs1221266964; called by muse, mutect2, varscan2
- COL11A1 | c.2584G>C p.G862R | Missense Mutation (SNP) | VAF 84/290 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62179137; called by muse, mutect2, varscan2
- COL8A1 | c.1783G>A p.V595M | Missense Mutation (SNP) | VAF 53/181 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs866517871, COSV53740890; called by muse, mutect2, varscan2
- CSMD3 | c.2876C>A p.S959* (on ENST00000297405 / NM_001363185.1; = p.S855* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 43/168 reads (26%) | catalogued as COSV52287772; called by muse, mutect2, varscan2
- CYP2A7 | c.1309C>T p.R437W | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1260568205; called by muse, mutect2
- DAAM1 | c.428C>G p.T143R | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1267063330; called by muse, mutect2
- DEFB118 | c.105G>C p.R35S | Missense Mutation (SNP) | VAF 35/244 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV99489358; called by muse, mutect2
- DIMT1 | c.164G>C p.R55T | Missense Mutation (SNP) | VAF 57/352 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.244); catalogued as rs762716422; called by muse, mutect2, varscan2
- DYNC2H1 | c.4357C>T p.H1453Y | Missense Mutation (SNP) | VAF 54/178 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770317460, COSV62101383; called by muse, mutect2, varscan2
- ELFN1 | c.432C>G p.I144M | Missense Mutation (SNP) | VAF 109/387 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV70034855; called by muse, mutect2, varscan2
- EXOC7 | c.97G>C p.E33Q | Missense Mutation (SNP) | VAF 21/170 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.358); catalogued as rs568286423; called by muse, mutect2, varscan2
- FADS2 | c.601G>A p.V201I | Missense Mutation (SNP) | VAF 37/276 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.05); catalogued as rs760024702, COSV53901142; called by muse, mutect2, varscan2
- FAM135A | c.4306G>C p.E1436Q (on ENST00000370479 / NM_001351599.1; = p.E1223Q on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 55/155 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV52048908; called by muse, mutect2, varscan2
- FAM155B | c.112G>C p.E38Q | Missense Mutation (SNP) | VAF 48/128 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99368278; called by muse, mutect2, varscan2
- FAM200A | c.988C>G p.H330D | Missense Mutation (SNP) | VAF 16/179 reads (9%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV68808761, COSV68809071; called by muse, mutect2
- FAM98C | c.215-5C>T | Splice Region (SNP) | VAF 43/416 reads (10%) | catalogued as rs772007009; called by muse, mutect2, varscan2
- FBXO47 | c.94G>A p.G32S | Missense Mutation (SNP) | VAF 32/246 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.049); catalogued as COSV100960823, COSV65241313; called by muse, mutect2, varscan2
- FOXG1 | c.745C>A p.P249T | Missense Mutation (SNP) | VAF 77/242 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57398901; called by muse, mutect2, varscan2
- G6PC2 | c.59G>A p.R20Q | Missense Mutation (SNP) | VAF 50/433 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs143670077; called by muse, mutect2, varscan2
- GRK2 | c.1579G>A p.D527N | Missense Mutation (SNP) | VAF 44/296 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as rs781074663, COSV57951461; called by muse, mutect2, varscan2
- HCRTR2 | c.73C>G p.Q25E | Missense Mutation (SNP) | VAF 79/518 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100904485, COSV63797697; called by muse, mutect2, varscan2
- HK3 | c.1240C>T p.R414W | Missense Mutation (SNP) | VAF 129/397 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs755568515, COSV52846463; called by muse, mutect2, varscan2
- IKZF3 | c.962G>A p.R321H | Missense Mutation (SNP) | VAF 166/597 reads (28%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.95); catalogued as rs1171389897, COSV53105779; called by muse, mutect2, varscan2
- IL17RC | c.1393G>A p.D465N (on ENST00000295981 / NM_153461.4; = p.D379N on NM_032732.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 69/189 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs764451235, COSV55974344; called by muse, mutect2, varscan2
- LAMA5 | c.218C>G p.S73C | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.579); catalogued as rs1238232872; called by muse, mutect2
- LARP4 | c.851G>A p.R284Q | Missense Mutation (SNP) | VAF 26/211 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as COSV53324696, COSV53327635; called by muse, mutect2, varscan2
- LTBP1 | c.4078G>C p.D1360H (on ENST00000404816 / NM_206943.4; = p.D1034H on NM_000627.4) | Missense Mutation (SNP) | VAF 37/338 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV55384372; called by muse, mutect2, varscan2
- LZTS1 | c.1267C>T p.R423W | Missense Mutation (SNP) | VAF 29/274 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs763490121, COSV99742601; called by muse, varscan2
- MED16 | c.14G>A p.R5Q | Missense Mutation (SNP) | VAF 88/194 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1424491141; called by muse, mutect2, varscan2
- MET | c.4060G>A p.A1354T | Missense Mutation (SNP) | VAF 59/467 reads (13%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs761522694, COSV59269068; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYL1 | c.287G>T p.G96V | Missense Mutation (SNP) | VAF 36/186 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58974422; called by muse, varscan2
- NLRX1 | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 65/407 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.026); catalogued as rs768298689; called by muse, mutect2, varscan2
- NRXN2 | c.3405C>T p.P1135= | Splice Region (SNP) | VAF 72/508 reads (14%) | catalogued as rs773013797, COSV55457915; called by muse, mutect2, varscan2
- NTM | c.821G>C p.R274T | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT tolerated (0.47); PolyPhen benign (0.012); catalogued as rs1356618882; called by muse, mutect2, varscan2
- NUDCD1 | c.1145G>A p.R382H | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); catalogued as COSV99517012; called by muse, mutect2, varscan2
- NVL | c.424G>T p.E142* | Nonsense Mutation (SNP) | VAF 67/213 reads (31%) | catalogued as COSV99894307; called by muse, mutect2, varscan2
- OR10J3 | c.140T>C p.M47T | Missense Mutation (SNP) | VAF 60/317 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as rs778476859; called by muse, mutect2, varscan2
- OR4C15 | c.875C>A p.T292N (on ENST00000314644; = p.T238N on NM_001001920.2) | Missense Mutation (SNP) | VAF 41/166 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.949); catalogued as rs760598418, COSV100115582; called by muse, mutect2, varscan2
- OR5AS1 | c.443C>A p.A148E | Missense Mutation (SNP) | VAF 28/306 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.658); catalogued as rs1377957215; called by muse, mutect2
- OR5J2 | c.554T>C p.L185P | Missense Mutation (SNP) | VAF 56/202 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1422473279; called by muse, mutect2, varscan2
- OR6C6 | c.466C>A p.P156T | Missense Mutation (SNP) | VAF 32/238 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.17); catalogued as COSV64455700; called by muse, mutect2, varscan2
- OR9A2 | c.442G>C p.G148R | Missense Mutation (SNP) | VAF 35/227 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63307174; called by muse, mutect2, varscan2
- OTUD7B | c.1064A>C p.D355A | Missense Mutation (SNP) | VAF 67/340 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782421208; called by muse, mutect2, varscan2
- PCDH15 | c.1456G>C p.G486R | Missense Mutation (SNP) | VAF 28/253 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1196401374, COSV57290777, COSV57399900; called by muse, mutect2, varscan2
- PCDH7 | c.862C>T p.R288C | Missense Mutation (SNP) | VAF 55/256 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62337676; called by muse, mutect2, varscan2
- PCDHA7 | c.1565C>T p.P522L | Missense Mutation (SNP) | VAF 313/877 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1554135483, COSV65347392; called by muse, mutect2, varscan2
- PHF3 | c.2837C>G p.S946* | Nonsense Mutation (SNP) | VAF 20/79 reads (25%) | catalogued as rs566004282; called by muse, mutect2, varscan2
- PHLDA1 | c.1079C>T p.S360F | Missense Mutation (SNP) | VAF 35/321 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.086); catalogued as rs367967233; called by muse, mutect2, varscan2
- PITPNM3 | c.100G>T p.E34* | Nonsense Mutation (SNP) | VAF 70/585 reads (12%) | catalogued as COSV52592620; called by muse, mutect2, varscan2
- PLCB1 | c.822G>C p.L274F | Missense Mutation (SNP) | VAF 47/170 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV62069864; called by muse, mutect2, varscan2
- PLCXD3 | c.928C>T p.L310F | Missense Mutation (SNP) | VAF 20/586 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV60616400; called by muse, mutect2
- PON2 | c.899C>T p.S300L | Missense Mutation (SNP) | VAF 56/433 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.048); catalogued as rs377508329; called by muse, mutect2, varscan2
- PTH1R | c.1198C>T p.R400W | Missense Mutation (SNP) | VAF 182/602 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775797881, COSV57317330; called by muse, mutect2, varscan2
- PTPN21 | c.1633G>A p.A545T | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.51); PolyPhen benign (0.031); catalogued as rs1351266214; called by muse, mutect2, varscan2
- QRICH2 | c.3309G>T p.R1103S | Missense Mutation (SNP) | VAF 40/283 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.184); catalogued as COSV53151210; called by muse, mutect2, varscan2
- RNF13 | c.766C>T p.L256F | Missense Mutation (SNP) | VAF 35/207 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53522557; called by muse, mutect2, varscan2
- RNF168 | c.880A>G p.I294V | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs532953013, COSV100534829; called by muse, mutect2, varscan2
- SFRP4 | c.526+1G>A p.X176_splice | Splice Site (SNP) | VAF 52/329 reads (16%) | catalogued as rs1198898000; called by muse, mutect2, varscan2
- SH2D4B | c.176C>A p.T59N | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.03); catalogued as rs1445581001; called by muse, mutect2, varscan2
- SI | c.2945C>T p.S982F | Missense Mutation (SNP) | VAF 75/406 reads (18%) | SIFT tolerated (0.69); PolyPhen benign (0.042); catalogued as rs1017230691; called by muse, mutect2, varscan2
- SLC17A6 | c.805G>T p.A269S | Missense Mutation (SNP) | VAF 71/226 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.1); catalogued as COSV54139993; called by muse, mutect2, varscan2
- SNTG2 | c.1124G>T p.G375V | Missense Mutation (SNP) | VAF 31/234 reads (13%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.796); catalogued as COSV104393896; called by muse, mutect2, varscan2
- STAG3 | c.2134A>G p.T712A | Missense Mutation (SNP) | VAF 56/364 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1205575445; called by muse, mutect2, varscan2
- SVOPL | c.628A>C p.I210L (on ENST00000419765; = p.I58L on NM_174959.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/201 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as COSV55991528; called by muse, mutect2, varscan2
- TERF2IP | c.234C>G p.F78L | Missense Mutation (SNP) | VAF 33/193 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.351); catalogued as rs1307842924; called by muse, mutect2, varscan2
- THEG | c.517T>C p.W173R | Missense Mutation (SNP) | VAF 52/153 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs968449268; called by muse, mutect2, varscan2
- TNFRSF11B | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 165/343 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.115); catalogued as rs1347938177; called by muse, mutect2, varscan2
- TUSC1 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 72/526 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.107); catalogued as rs1401432805; called by muse, mutect2, varscan2
- UBC | c.61G>A p.D21N | Missense Mutation (SNP) | VAF 63/390 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as COSV60058140; called by muse, mutect2, varscan2
- VPS8 | c.4195A>C p.S1399R (on ENST00000625842 / NM_001349294.1; = p.S1397R on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/394 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs577176989; called by muse, mutect2
- VTA1 | c.76G>T p.E26* | Nonsense Mutation (SNP) | VAF 86/318 reads (27%) | catalogued as COSV100859271; called by muse, mutect2, varscan2
- VWA5B1 | c.2273G>C p.R758T | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs564566358; called by mutect2, varscan2
- WAPL | c.2329G>A p.E777K | Missense Mutation (SNP) | VAF 39/209 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV53934040; called by muse, mutect2, varscan2
- WBP4 | c.1115G>A p.R372Q | Missense Mutation (SNP) | VAF 69/151 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200281123; called by muse, mutect2, varscan2
- XAB2 | c.1577T>C p.M526T | Missense Mutation (SNP) | VAF 42/358 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs374151176; called by muse, mutect2, varscan2
- XPOT | c.1939C>G p.L647V | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.046); catalogued as COSV60346347; called by mutect2, varscan2
- ZNF225 | c.205G>T p.E69* | Nonsense Mutation (SNP) | VAF 46/265 reads (17%) | catalogued as COSV53471659; called by muse, mutect2, varscan2
- ZNF43 | c.496A>G p.I166V | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.026); catalogued as COSV99048996; called by muse, mutect2, varscan2
- ZNF556 | c.658G>C p.E220Q | Missense Mutation (SNP) | VAF 42/307 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.042); catalogued as COSV56913008; called by muse, mutect2, varscan2
- ZNF626 | c.1504A>T p.I502F | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as rs200411264, COSV74128957; called by mutect2, varscan2
- ZNF626 | c.653G>A p.R218K | Missense Mutation (SNP) | VAF 86/399 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs201065845, COSV74130502; called by muse, mutect2, varscan2
- A1CF | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 39/261 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- AC008397.2 | c.1496C>T p.T499I | Missense Mutation (SNP) | VAF 32/192 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACSM1 | c.515T>A p.V172E | Missense Mutation (SNP) | VAF 152/488 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ADAMTS12 | c.984C>G p.I328M | Missense Mutation (SNP) | VAF 136/313 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ADAMTSL2 | c.674C>A p.A225D | Missense Mutation (SNP) | VAF 102/728 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- ADCY8 | c.2223G>A p.M741I | Missense Mutation (SNP) | VAF 31/191 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- AHNAK | c.5630T>G p.V1877G | Missense Mutation (SNP) | VAF 139/432 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AHNAK | c.3884C>A p.P1295Q | Missense Mutation (SNP) | VAF 87/556 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- AKAP8L | c.1438G>T p.E480* | Nonsense Mutation (SNP) | VAF 51/316 reads (16%) | called by muse, mutect2, varscan2
- AMOTL1 | c.1507A>T p.K503* | Nonsense Mutation (SNP) | VAF 27/140 reads (19%) | called by muse, mutect2, varscan2
- ANK3 | c.5018C>T p.S1673L | Missense Mutation (SNP) | VAF 112/325 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ARHGAP21 | c.1454C>G p.S485C | Missense Mutation (SNP) | VAF 34/158 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- ARHGAP32 | c.3848C>A p.A1283D (on ENST00000310343 / NM_001378025.1; = p.A934D on NM_014715.4) | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.017); called by muse, mutect2
- ATOH1 | c.181C>A p.P61T | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- BMP2K | c.1983G>T p.K661N | Missense Mutation (SNP) | VAF 58/168 reads (35%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- BPTF | c.8556G>C p.K2852N | Missense Mutation (SNP) | VAF 40/245 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BTBD8 | c.730C>G p.Q244E | Missense Mutation (SNP) | VAF 46/248 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- BTRC | c.682C>G p.L228V (on ENST00000370187 / NM_033637.4; = p.L192V on NM_003939.5) | Missense Mutation (SNP) | VAF 58/236 reads (25%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); called by muse, mutect2
- C1QL3 | c.629A>T p.Y210F | Missense Mutation (SNP) | VAF 36/155 reads (23%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- C1QTNF4 | c.76T>C p.S26P | Missense Mutation (SNP) | VAF 59/441 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- CALCR | c.191del p.A64Dfs*79 | Frame Shift Del (DEL) | VAF 25/151 reads (17%) | called by mutect2, pindel
- CALD1 | c.966A>T p.K322N | Missense Mutation (SNP) | VAF 68/474 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.168); called by muse, varscan2
- CAMSAP2 | c.2619G>A p.W873* (on ENST00000236925 / NM_001297707.2; = p.W862* on NM_203459.3) | Nonsense Mutation (SNP) | VAF 31/179 reads (17%) | called by muse, mutect2, varscan2
- CD163L1 | c.647C>A p.P216H | Missense Mutation (SNP) | VAF 243/471 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- CEP170 | c.1970G>A p.S657N | Missense Mutation (SNP) | VAF 42/520 reads (8%) | SIFT tolerated (0.48); PolyPhen benign (0.001); called by muse, mutect2
- CETN1 | c.166G>T p.A56S | Missense Mutation (SNP) | VAF 37/283 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- CIP2A | c.1565G>A p.R522K | Missense Mutation (SNP) | VAF 33/138 reads (24%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CLDN18 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 43/338 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- CLMN | c.2000G>T p.R667L | Missense Mutation (SNP) | VAF 85/267 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- CPLANE1 | c.*4921-1G>A | Splice Site (SNP) | VAF 17/139 reads (12%) | called by muse, mutect2, varscan2
- CRACD | c.1888G>A p.A630T | Missense Mutation (SNP) | VAF 96/233 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CRISP2 | c.247A>T p.S83C | Missense Mutation (SNP) | VAF 35/202 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DDX11 | c.999G>C p.E333D | Missense Mutation (SNP) | VAF 91/1252 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.015); called by muse, mutect2
- DOCK6 | c.2870A>C p.K957T | Missense Mutation (SNP) | VAF 82/346 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- DRC1 | c.1391G>T p.R464L | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DRC7 | c.260A>G p.N87S | Missense Mutation (SNP) | VAF 27/179 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DSP | c.1130_1140+12del p.X377_splice | Splice Site (DEL) | VAF 44/310 reads (14%) | called by mutect2, pindel
- DYNC2H1 | c.2599G>C p.D867H | Missense Mutation (SNP) | VAF 44/158 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- EHBP1L1 | c.1912G>C p.V638L | Missense Mutation (SNP) | VAF 20/147 reads (14%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- EIF4A2 | c.528G>A p.W176* | Nonsense Mutation (SNP) | VAF 16/132 reads (12%) | called by muse, mutect2, varscan2
- EIF4E2 | c.244A>G p.I82V | Missense Mutation (SNP) | VAF 42/207 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- ENPP3 | c.347C>A p.S116* | Nonsense Mutation (SNP) | VAF 38/240 reads (16%) | called by muse, mutect2, varscan2
- EOMES | c.127C>T p.P43S | Missense Mutation (SNP) | VAF 215/425 reads (51%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- EPO | c.560C>A p.A187D | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- EXOC4 | c.2862G>C p.E954D | Missense Mutation (SNP) | VAF 37/140 reads (26%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- FAM170B | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- FAT1 | c.4250_4256del p.L1417Qfs*28 | Frame Shift Del (DEL) | VAF 34/180 reads (19%) | called by mutect2, pindel, varscan2
- FAT4 | c.1468C>T p.P490S | Missense Mutation (SNP) | VAF 40/188 reads (21%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- FBXL13 | c.1685C>A p.S562Y | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FCHO1 | c.2519C>G p.S840* | Nonsense Mutation (SNP) | VAF 63/253 reads (25%) | called by muse, mutect2, varscan2
- FOXD4L1 | c.913C>G p.Q305E | Missense Mutation (SNP) | VAF 270/1172 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- GALR1 | c.994A>T p.K332* | Nonsense Mutation (SNP) | VAF 87/211 reads (41%) | called by muse, mutect2, varscan2
- GAPVD1 | c.4184A>T p.Q1395L (on ENST00000394104; = p.Q1404L on NM_015635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/278 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- GASK1B | c.628G>T p.E210* | Nonsense Mutation (SNP) | VAF 95/316 reads (30%) | called by muse, mutect2, varscan2
- GBA2 | c.1987G>A p.D663N | Missense Mutation (SNP) | VAF 35/301 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- GDF2 | c.385del p.Q129Rfs*38 | Frame Shift Del (DEL) | VAF 49/197 reads (25%) | called by mutect2, pindel, varscan2
- GLDC | c.1363C>G p.Q455E | Missense Mutation (SNP) | VAF 79/476 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GP5 | c.1505A>C p.E502A | Missense Mutation (SNP) | VAF 27/227 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GP5 | c.1504G>T p.E502* | Nonsense Mutation (SNP) | VAF 27/220 reads (12%) | called by muse, mutect2, varscan2
- GPC2 | c.1123G>C p.E375Q | Missense Mutation (SNP) | VAF 22/220 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.715); called by muse, mutect2
- GPR137B | c.1166C>G p.S389* | Nonsense Mutation (SNP) | VAF 25/246 reads (10%) | called by muse, mutect2, varscan2
- GPR152 | c.1131C>A p.N377K | Missense Mutation (SNP) | VAF 69/373 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- GUCY1A1 | c.1189G>A p.G397R | Missense Mutation (SNP) | VAF 62/188 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HDAC9 | c.1158G>C p.K386N | Missense Mutation (SNP) | VAF 26/318 reads (8%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.622); called by muse, mutect2
- HERC4 | c.1378A>G p.M460V | Missense Mutation (SNP) | VAF 42/177 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IGLV1-40 | c.164A>G p.H55R | Missense Mutation (SNP) | VAF 70/568 reads (12%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- IL11RA | c.926C>G p.P309R | Missense Mutation (SNP) | VAF 385/800 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); called by muse, mutect2, varscan2
- IQGAP1 | c.3386C>G p.T1129R | Missense Mutation (SNP) | VAF 118/427 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ITPR2 | c.5735G>A p.S1912N | Missense Mutation (SNP) | VAF 62/556 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- KCNH1 | c.2618C>A p.T873K (on ENST00000271751 / NM_172362.3; = p.T846K on NM_002238.4) | Missense Mutation (SNP) | VAF 76/481 reads (16%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- KCTD14 | c.467C>A p.A156E | Missense Mutation (SNP) | VAF 35/233 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KIAA0895 | c.633C>G p.F211L (on ENST00000297063 / NM_001100425.2; = p.F160L on NM_015314.3) | Missense Mutation (SNP) | VAF 54/239 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LAMA1 | c.5721C>G p.Y1907* | Nonsense Mutation (SNP) | VAF 126/528 reads (24%) | called by muse, mutect2, varscan2
- LARGE1 | c.1174A>T p.K392* | Nonsense Mutation (SNP) | VAF 83/319 reads (26%) | called by muse, mutect2, varscan2
- LILRA6 | c.524G>T p.G175V | Missense Mutation (SNP) | VAF 44/491 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- LIMK1 | c.343G>C p.G115R | Missense Mutation (SNP) | VAF 17/147 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LRRIQ3 | c.356C>A p.S119Y | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); called by muse, mutect2
- LZTR1 | c.1768C>A p.Q590K | Missense Mutation (SNP) | VAF 38/251 reads (15%) | SIFT tolerated (0.77); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- MAD1L1 | c.86C>G p.S29C | Missense Mutation (SNP) | VAF 74/331 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- MBD1 | c.155A>G p.Y52C | Missense Mutation (SNP) | VAF 259/529 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MORC1 | c.2801G>A p.G934D | Missense Mutation (SNP) | VAF 47/171 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- MPHOSPH9 | c.3206G>A p.G1069E | Missense Mutation (SNP) | VAF 82/512 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- MUC16 | c.19568C>A p.P6523Q | Missense Mutation (SNP) | VAF 19/155 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- MUC6 | c.5023A>C p.T1675P | Missense Mutation (SNP) | VAF 126/1036 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); called by muse, varscan2
- MYO3A | c.3111del p.V1038Cfs*11 | Frame Shift Del (DEL) | VAF 54/362 reads (15%) | called by mutect2, pindel, varscan2
- MYT1L | c.1606C>G p.P536A | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- NCR3LG1 | c.1328C>G p.S443C | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NDUFV2 | c.37G>T p.G13C | Missense Mutation (SNP) | VAF 43/414 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- NEUROD6 | c.391T>G p.S131A | Missense Mutation (SNP) | VAF 73/427 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- NFE2L2 | c.1345C>A p.R449S | Missense Mutation (SNP) | VAF 115/293 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- NKX2-6 | c.754T>C p.Y252H | Missense Mutation (SNP) | VAF 32/261 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- NOS2 | c.139C>T p.H47Y | Missense Mutation (SNP) | VAF 33/170 reads (19%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- NTRK3 | c.538G>C p.A180P | Missense Mutation (SNP) | VAF 148/495 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- NUTM1 | c.855-1G>A p.X285_splice | Splice Site (SNP) | VAF 45/156 reads (29%) | called by muse, mutect2, varscan2
- NUTM1 | c.3133G>T p.G1045C | Missense Mutation (SNP) | VAF 93/360 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- OPTN | c.1088T>A p.L363Q | Missense Mutation (SNP) | VAF 31/221 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR6C1 | c.542del p.P181Hfs*13 | Frame Shift Del (DEL) | VAF 24/178 reads (13%) | called by mutect2, pindel, varscan2
- OTOGL | c.2726C>A p.P909Q (on ENST00000547103; = p.P900Q on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/246 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDHA1 | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 75/199 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDHB16 | c.1622T>G p.L541R | Missense Mutation (SNP) | VAF 190/500 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); called by muse, varscan2
- PHF20 | c.872C>G p.S291* | Nonsense Mutation (SNP) | VAF 10/246 reads (4%) | called by muse, mutect2
- PIKFYVE | c.3078T>A p.Y1026* | Nonsense Mutation (SNP) | VAF 56/300 reads (19%) | called by muse, mutect2, varscan2
- PLIN4 | c.699del p.N233Kfs*18 (on ENST00000301286; = p.N248Kfs*18 on NM_001367868.2) | Frame Shift Del (DEL) | VAF 260/770 reads (34%) | called by pindel, varscan2
- PLXNA1 | c.5629_5630del p.R1877Afs*29 | Frame Shift Del (DEL) | VAF 52/248 reads (21%) | called by pindel, varscan2
- PLXNA4 | c.4384T>C p.F1462L | Missense Mutation (SNP) | VAF 22/288 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.403); called by muse, mutect2
- POLE2 | c.602C>G p.T201S | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.06); called by muse, mutect2
- POU4F1 | c.61A>G p.K21E | Missense Mutation (SNP) | VAF 56/158 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- POU4F1 | c.60C>A p.H20Q | Missense Mutation (SNP) | VAF 56/158 reads (35%) | SIFT tolerated, low confidence (0.39); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- PPP1R9A | c.1525A>G p.K509E | Missense Mutation (SNP) | VAF 43/158 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRKAB2 | c.5G>C p.G2A | Missense Mutation (SNP) | VAF 36/178 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- PTDSS2 | c.375G>C p.W125C | Missense Mutation (SNP) | VAF 52/242 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- PTPRB | c.3453G>C p.K1151N | Missense Mutation (SNP) | VAF 44/251 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- RACK1 | c.792G>T p.K264N | Missense Mutation (SNP) | VAF 13/161 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2
- RCC1 | c.273C>A p.F91L | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- RGS9 | c.1505C>G p.S502C | Missense Mutation (SNP) | VAF 39/224 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RNPC3 | c.1117A>G p.I373V | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- RP1 | c.2943G>T p.L981F | Missense Mutation (SNP) | VAF 35/310 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- RTL10 | c.1015G>C p.E339Q | Missense Mutation (SNP) | VAF 29/260 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.662); called by muse, mutect2, varscan2
- RUBCNL | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 138/415 reads (33%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- SAMD12 | c.357_358insTT p.E120Lfs*22 | Frame Shift Ins (INS) | VAF 23/155 reads (15%) | called by mutect2, pindel, varscan2
- SARM1 | c.280G>T p.E94* | Nonsense Mutation (SNP) | VAF 34/225 reads (15%) | called by muse, mutect2, varscan2
- SBF2 | c.4365G>C p.Q1455H | Missense Mutation (SNP) | VAF 55/243 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SHROOM4 | c.3235G>A p.E1079K | Missense Mutation (SNP) | VAF 55/93 reads (59%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- SOWAHB | c.916A>T p.T306S | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.681); called by muse, mutect2, varscan2
- SPI1 | c.189G>C p.E63D | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.076); called by mutect2, varscan2
- SRCAP | c.7832T>A p.L2611* | Nonsense Mutation (SNP) | VAF 101/357 reads (28%) | called by muse, mutect2, varscan2
- SRGAP1 | c.1724C>T p.S575L | Missense Mutation (SNP) | VAF 45/272 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- SRRM2 | c.922G>A p.A308T | Missense Mutation (SNP) | VAF 170/683 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- SST | c.257T>A p.L86Q | Missense Mutation (SNP) | VAF 74/1096 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2
- SV2A | c.1031C>G p.S344C | Missense Mutation (SNP) | VAF 76/293 reads (26%) | SIFT tolerated (0.96); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SYCP2 | c.776C>G p.T259R | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TARDBP | c.858G>C p.Q286H | Missense Mutation (SNP) | VAF 34/190 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- TBC1D26 | c.362A>T p.K121M | Missense Mutation (SNP) | VAF 32/235 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- THSD7A | c.4190G>T p.G1397V | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- TMEM167A | c.170T>C p.V57A | Missense Mutation (SNP) | VAF 67/232 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- TMEM94 | c.2267G>A p.C756Y | Missense Mutation (SNP) | VAF 76/691 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TPTE | c.1090G>A p.E364K (on ENST00000618007 / NM_199261.4; = p.E346K on NM_199259.4) | Missense Mutation (SNP) | VAF 42/302 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- TRAPPC12 | c.1470C>G p.Y490* | Nonsense Mutation (SNP) | VAF 48/313 reads (15%) | called by muse, mutect2, varscan2
- TRIM21 | c.255G>C p.E85D | Missense Mutation (SNP) | VAF 59/287 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TRPM2 | c.1669C>T p.Q557* | Nonsense Mutation (SNP) | VAF 70/406 reads (17%) | called by muse, mutect2, varscan2
- TRPV2 | c.2143G>C p.E715Q | Missense Mutation (SNP) | VAF 32/212 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- TUBA4A | c.1091C>T p.P364L | Missense Mutation (SNP) | VAF 80/373 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- UTP14A | c.1189C>T p.P397S | Missense Mutation (SNP) | VAF 55/95 reads (58%) | SIFT tolerated (0.22); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- VPS13B | c.8307G>C p.Q2769H | Missense Mutation (SNP) | VAF 37/324 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZFHX3 | c.5638T>G p.L1880V | Missense Mutation (SNP) | VAF 20/300 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.01); called by muse, mutect2
- ZNF10 | c.160+1G>T p.X54_splice | Splice Site (SNP) | VAF 16/100 reads (16%) | called by muse, mutect2
- ZNF282 | c.1749C>G p.Y583* | Nonsense Mutation (SNP) | VAF 57/462 reads (12%) | called by muse, mutect2, varscan2
- ZNF608 | c.934C>G p.P312A | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF626 | c.1336A>T p.I446F | Missense Mutation (SNP) | VAF 86/266 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); called by muse, varscan2
- ZNF804A | c.590dup p.N197Kfs*2 | Frame Shift Ins (INS) | VAF 17/134 reads (13%) | called by mutect2, pindel, varscan2
- ZNF827 | c.686C>T p.T229I | Missense Mutation (SNP) | VAF 39/168 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ALPP | c.162C>A p.A54= | Silent (SNP) | VAF 63/410 reads (15%) | catalogued as COSV101235188; called by muse, mutect2, varscan2
- ARFGEF3 | c.2304C>T p.F768= | Silent (SNP) | VAF 47/131 reads (36%) | catalogued as COSV52466340; called by muse, mutect2, varscan2
- ARHGAP21 | c.4122G>A p.R1374= | Silent (SNP) | VAF 21/141 reads (15%) | called by muse, mutect2, varscan2
- CFAP46 | c.6996C>T p.D2332= | Silent (SNP) | VAF 32/147 reads (22%) | called by muse, mutect2, varscan2
- CFAP57 | c.666C>A p.L222= | Silent (SNP) | VAF 48/205 reads (23%) | catalogued as COSV65264278, COSV65264337; called by muse, mutect2, varscan2
- CHD8 | c.3090G>A p.L1030= (on ENST00000646647 / NM_001170629.2; = p.L751= on NM_020920.4) | Silent (SNP) | VAF 43/194 reads (22%) | catalogued as COSV101303242; called by muse, mutect2, varscan2
- CNTNAP4 | c.3477A>C p.A1159= | Silent (SNP) | VAF 32/184 reads (17%) | catalogued as rs1282700797; called by muse, mutect2, varscan2
- CNTNAP5 | c.3141C>A p.T1047= | Silent (SNP) | VAF 46/461 reads (10%) | catalogued as rs369865347; called by muse, mutect2, varscan2
- COA8 | c.357T>C p.T119= | Silent (SNP) | VAF 43/126 reads (34%) | called by muse, mutect2, varscan2
- CPT1B | c.1842C>G p.A614= | Silent (SNP) | VAF 69/257 reads (27%) | called by muse, mutect2, varscan2
- CSMD1 | c.1962T>A p.T654= (on ENST00000520002; = p.T653= on NM_033225.6) | Silent (SNP) | VAF 84/388 reads (22%) | catalogued as COSV100152939; called by muse, mutect2, varscan2
- CYFIP2 | c.3691C>A p.R1231= (on ENST00000616178 / NM_001291722.2; = p.R1206= on NM_014376.4) | Silent (SNP) | VAF 55/134 reads (41%) | catalogued as COSV59042298; called by muse, mutect2, varscan2
- D2HGDH | c.246G>T p.P82= | Silent (SNP) | VAF 65/323 reads (20%) | called by muse, mutect2, varscan2
- DCAF8L2 | c.639C>A p.A213= | Silent (SNP) | VAF 38/137 reads (28%) | called by muse, mutect2, varscan2
- DHX36 | c.2649C>T p.Y883= | Silent (SNP) | VAF 45/198 reads (23%) | called by muse, mutect2, varscan2
- EPG5 | c.5790C>T p.F1930= | Silent (SNP) | VAF 74/275 reads (27%) | catalogued as rs1377219038; called by muse, mutect2, varscan2
- FAM169A | c.123C>G p.L41= | Silent (SNP) | VAF 44/122 reads (36%) | called by muse, mutect2, varscan2
- FAT3 | c.3531C>T p.S1177= | Silent (SNP) | VAF 40/280 reads (14%) | catalogued as rs771482221; called by muse, mutect2, varscan2
- FLT1 | c.1128G>A p.A376= | Silent (SNP) | VAF 75/237 reads (32%) | catalogued as rs375304310; called by muse, mutect2, varscan2
- GAPVD1 | c.2193G>A p.Q731= | Silent (SNP) | VAF 46/234 reads (20%) | called by muse, mutect2, varscan2
- GPRC5B | c.702C>T p.A234= | Silent (SNP) | VAF 132/677 reads (19%) | called by muse, mutect2, varscan2
- HECTD3 | c.93C>A p.R31= | Silent (SNP) | VAF 30/123 reads (24%) | called by muse, mutect2, varscan2
- ITPKB | c.1293C>T p.P431= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as rs753117375; called by muse, mutect2, varscan2
- ITPR2 | c.5925C>G p.L1975= | Silent (SNP) | VAF 111/712 reads (16%) | called by muse, mutect2, varscan2
- KCNMB4 | c.120G>C p.L40= | Silent (SNP) | VAF 52/442 reads (12%) | called by muse, mutect2, varscan2
- KIF5A | c.1227C>T p.I409= | Silent (SNP) | VAF 30/255 reads (12%) | catalogued as rs775172912, COSV54059307; called by muse, mutect2, varscan2
- LRFN2 | c.441C>T p.F147= | Silent (SNP) | VAF 71/347 reads (20%) | catalogued as rs1330493513, COSV57825644; called by muse, mutect2, varscan2
- LTB | c.474G>T p.T158= | Silent (SNP) | VAF 49/219 reads (22%) | catalogued as rs757889756; called by muse, mutect2, varscan2
- MAG | c.684C>T p.F228= | Silent (SNP) | VAF 18/192 reads (9%) | called by muse, mutect2
- MED13 | c.5724C>T p.S1908= | Silent (SNP) | VAF 28/270 reads (10%) | catalogued as rs369004340; called by muse, mutect2, varscan2
- MKLN1 | c.555A>G p.R185= | Silent (SNP) | VAF 37/357 reads (10%) | called by muse, mutect2, varscan2
- MKRN2 | c.720C>T p.I240= | Silent (SNP) | VAF 69/252 reads (27%) | catalogued as COSV50108385; called by muse, mutect2, varscan2
- NDST1 | c.1530C>T p.N510= | Silent (SNP) | VAF 33/150 reads (22%) | catalogued as rs763620272, COSV55788026; ClinVar: likely benign; called by muse, mutect2, varscan2
- NPHS1 | c.1728C>T p.V576= | Silent (SNP) | VAF 124/389 reads (32%) | called by muse, mutect2, varscan2
- NPTX2 | c.1074C>A p.T358= | Silent (SNP) | VAF 9/71 reads (13%) | called by muse, mutect2, varscan2
- NUDT19 | c.819C>G p.L273= | Silent (SNP) | VAF 76/1030 reads (7%) | called by muse, mutect2
- NXPE2 | c.1426C>T p.L476= | Silent (SNP) | VAF 28/280 reads (10%) | catalogued as COSV64941668; called by muse, mutect2
- OCSTAMP | c.1194C>T p.R398= | Silent (SNP) | VAF 26/97 reads (27%) | catalogued as rs1332264044; called by muse, mutect2, varscan2
- ONECUT2 | c.702C>T p.N234= | Silent (SNP) | VAF 52/388 reads (13%) | catalogued as rs756746181; called by muse, mutect2, varscan2
- OR4C15 | c.348G>A p.L116= (on ENST00000314644; = p.L62= on NM_001001920.2) | Silent (SNP) | VAF 32/176 reads (18%) | called by muse, mutect2, varscan2
- OR4X1 | c.651G>T p.L217= | Silent (SNP) | VAF 163/399 reads (41%) | called by muse, mutect2, varscan2
- PCDHGA1 | c.1548G>T p.A516= | Silent (SNP) | VAF 82/231 reads (35%) | catalogued as rs752057797; called by muse, mutect2, varscan2
- PIK3R5 | c.2001C>T p.A667= | Silent (SNP) | VAF 24/89 reads (27%) | called by muse, mutect2, varscan2
- POP4 | c.168G>A p.V56= | Silent (SNP) | VAF 192/528 reads (36%) | called by muse, mutect2, varscan2
- PRAMEF2 | c.81C>T p.A27= | Silent (SNP) | VAF 60/388 reads (15%) | catalogued as rs147106339, COSV53574573; called by muse, varscan2
- RAB33B | c.651G>C p.L217= | Silent (SNP) | VAF 17/78 reads (22%) | called by muse, mutect2, varscan2
- RNFT2 | c.903C>T p.I301= | Silent (SNP) | VAF 44/312 reads (14%) | catalogued as rs773306690; called by muse, mutect2, varscan2
- SLC6A13 | c.945C>T p.I315= | Silent (SNP) | VAF 100/293 reads (34%) | catalogued as rs76138594; called by muse, mutect2, varscan2
- SLC8A2 | c.1830G>A p.E610= | Silent (SNP) | VAF 51/186 reads (27%) | catalogued as rs377308748; called by muse, mutect2, varscan2
- SPTAN1 | c.4524C>T p.A1508= | Silent (SNP) | VAF 108/600 reads (18%) | catalogued as rs371100708; ClinVar: likely benign; called by muse, mutect2, varscan2
- SULT1C4 | c.516G>A p.G172= | Silent (SNP) | VAF 4/94 reads (4%) | called by muse, mutect2
- TAF8 | c.399C>A p.A133= | Silent (SNP) | VAF 32/199 reads (16%) | called by muse, mutect2, varscan2
- TDRD15 | c.2325C>T p.L775= | Silent (SNP) | VAF 19/154 reads (12%) | called by muse, mutect2, varscan2
- TMEM255B | c.954G>A p.G318= | Silent (SNP) | VAF 41/259 reads (16%) | catalogued as COSV64711539; called by muse, mutect2, varscan2
- TNN | c.201C>T p.D67= | Silent (SNP) | VAF 46/270 reads (17%) | catalogued as rs779026691, COSV53432709; called by muse, mutect2, varscan2
- TTN | c.77331C>A p.T25777= (on ENST00000591111; = p.T18353= on NM_003319.4) | Silent (SNP) | VAF 72/246 reads (29%) | catalogued as rs763746509; called by muse, mutect2, varscan2
- TTN | c.34707G>A p.K11569= (on ENST00000591111; = p.K10642= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 44/342 reads (13%) | called by muse, mutect2, varscan2
- ULK1 | c.2409T>G p.P803= | Silent (SNP) | VAF 38/283 reads (13%) | called by muse, mutect2, varscan2
- UNC80 | c.984C>T p.T328= | Silent (SNP) | VAF 52/216 reads (24%) | catalogued as COSV55907220; called by muse, mutect2, varscan2
- ANK1 | c.5395-1107G>C | Intron (SNP) | VAF 71/456 reads (16%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65503558 del AT | 5'Flank (DEL) | VAF 16/108 reads (15%) | called by mutect2, pindel, varscan2
- ATL3 | chr11:63671697 C>T | 5'Flank (SNP) | VAF 27/118 reads (23%) | catalogued as rs1327420848; called by muse, mutect2, varscan2
- BIN2 | c.*15G>A | 3'UTR (SNP) | VAF 28/177 reads (16%) | called by muse, mutect2, varscan2
- C7orf50 | c.130-18156C>T | Intron (SNP) | VAF 18/93 reads (19%) | catalogued as rs753916746; called by muse, mutect2, varscan2
- CANX | c.-46G>A | 5'UTR (SNP) | VAF 8/12 reads (67%) | called by muse, mutect2
- CAPN1 | chr11:65181491 G>C | 5'Flank (SNP) | VAF 14/66 reads (21%) | catalogued as rs1439850805; called by muse, mutect2, varscan2
- CPT1B | c.971-187G>C | Intron (SNP) | VAF 39/292 reads (13%) | catalogued as rs1272399402; called by muse, mutect2, varscan2
- DCC | c.-28C>T | 5'UTR (SNP) | VAF 50/367 reads (14%) | catalogued as rs1241363759; called by muse, mutect2, varscan2
- GPC1 | c.167-8378C>G | Intron (SNP) | VAF 23/168 reads (14%) | called by muse, mutect2, varscan2
- ING5 | c.388+9G>T | Intron (SNP) | VAF 10/52 reads (19%) | called by muse, varscan2
- IQSEC3 | c.3114+113C>T | Intron (SNP) | VAF 86/345 reads (25%) | called by muse, mutect2, varscan2
- ISCU | c.115-172G>A | Intron (SNP) | VAF 56/382 reads (15%) | called by muse, mutect2, varscan2
- KRT8P11 | n.257G>C | RNA (SNP) | VAF 74/408 reads (18%) | called by muse, mutect2, varscan2
- LETMD1 | c.915+68G>T | Intron (SNP) | VAF 42/252 reads (17%) | called by muse, mutect2, varscan2
- LIG3 | c.-73G>C | 5'UTR (SNP) | VAF 35/294 reads (12%) | called by muse, mutect2, varscan2
- LVRN | c.2038-121G>T | Intron (SNP) | VAF 39/211 reads (18%) | called by muse, mutect2, varscan2
- MAP4K4 | c.1867-1007C>T | Intron (SNP) | VAF 41/333 reads (12%) | catalogued as rs1286174346; called by muse, mutect2, varscan2
- MGA | c.4435-80A>G | Intron (SNP) | VAF 85/328 reads (26%) | catalogued as rs201833815; called by muse, mutect2, varscan2
- MYADML | n.619G>A | RNA (SNP) | VAF 36/258 reads (14%) | catalogued as rs574694619; called by muse, mutect2, varscan2
- NOC2LP2 | n.361C>T | RNA (SNP) | VAF 75/465 reads (16%) | called by muse, mutect2, varscan2
- NUGGC | c.-10G>A | 5'UTR (SNP) | VAF 42/331 reads (13%) | catalogued as rs758531764, COSV58435314; called by muse, mutect2, varscan2
- NXF5 | n.1916G>A | RNA (SNP) | VAF 154/220 reads (70%) | called by muse, mutect2, varscan2
- OR8H1 | c.*70C>T | 3'UTR (SNP) | VAF 5/85 reads (6%) | catalogued as rs774692922, COSV57294429; called by muse, mutect2
- PAH | c.707-44C>G | Intron (SNP) | VAF 58/326 reads (18%) | called by muse, mutect2, varscan2
- PCGF3 | c.109+176A>T | Intron (SNP) | VAF 48/371 reads (13%) | called by muse, mutect2, varscan2
- PDE7A | c.-13G>A | 5'UTR (SNP) | VAF 43/239 reads (18%) | called by muse, mutect2, varscan2
- PECAM1 | c.*1888C>A | 3'UTR (SNP) | VAF 25/94 reads (27%) | called by muse, mutect2, varscan2
- RNF170 | c.*1058A>G | 3'UTR (SNP) | VAF 55/549 reads (10%) | called by muse, mutect2
- SNORD116-10 | chr15:25077038 A>T | 3'Flank (SNP) | VAF 59/293 reads (20%) | called by muse, mutect2, varscan2
- SSPOP | n.10825del | RNA (DEL) | VAF 29/122 reads (24%) | catalogued as COSV65137329; called by mutect2, pindel, varscan2
- TPRX2P | n.342A>G | RNA (SNP) | VAF 45/289 reads (16%) | called by muse, mutect2, varscan2
- TUT1 | chr11:62574869 C>T | 3'Flank (SNP) | VAF 55/321 reads (17%) | catalogued as rs1026382509; called by muse, mutect2, varscan2
- UTP4 | c.1834-15T>C | Intron (SNP) | VAF 14/168 reads (8%) | called by muse, mutect2
- ZFP28 | c.898+91G>T | Intron (SNP) | VAF 34/291 reads (12%) | called by muse, mutect2, varscan2
- ZNF606 | c.-236C>G | 5'UTR (SNP) | VAF 23/185 reads (12%) | called by muse, mutect2, varscan2
